Surgical pathology report (de-identified scan), TCGA case TCGA-52-7812, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site University of Miami, specimen TCGA-52-7812-01A (Primary Tumor).

[page 1 of 4]
Pathologic Interpretation:

- A. Left upper lobe biopsy, [REDACTED]
- No malignancy seen.
- B. Left secondary carina, [REDACTED]
- No malignancy seen.
- C. Station 4L mediastinal lymph node, [REDACTED]
- Fragmented one (1) lymph node, no malignancy seen.
- D. Left lung tumor for frozen section for bronchial margins, [REDACTED]
- Poorly differentiated squamous cell carcinoma, 6.0 cm in greatest dimension.
- Large vessel invasion is present.
- Pleural invasion is present.
- Bronchial margin free of tumor.
- Non-neoplastic lung shows post-obstructive pneumonia.
- One (1) intraparenchymal lymph node, no malignancy seen.
- AJCC: pTX N2 MX (Section of chest wall lesion on specimen I pending).
- E. Station 5 lymph node # 1:
- Metastatic carcinoma in one lymph node (1/1).
- F. Station 5 lymph node # 2:
- Metastatic carcinoma in two lymph nodes examined (2/2).
- G. Station 5 lymph node # 3:
- No malignancy seen in two (2) lymph nodes examined.
- H. Station 9 lymph node:
- No malignancy seen in one (1) lymph node examined.
- I. Left chest with ribs 2 R3 for representation margins short stitch superior, long stitch lateral, FS:
- Fibrosis and chronic inflammation.
- The external surface is free of malignancy.
- Section of bone and soft tissue pending.

Tumor Summary:

Specimen Type

- Pneumonectomy

Laterality

- Left

Tumor Site

- Not specified

Tumor Size

- Greatest dimension: 6 cm
- *Additional dimensions: 5 x 4.5 cm

Histologic Type

- Squamous cell carcinoma

Histologic Grade

- G3: Poorly differentiated

[page 2 of 4]
Margins

- Margins uninvolved by invasive carcinoma.
- Distance of invasive carcinoma from closest margin: 2 mm
- Specify margin: Bronchial

Direct Extension of Tumor

- Visceral pleura

Venous (Large Vessel) Invasion (V)

- Present

As the attending pathologist, I attest that I: (i) Examined the relevant preparation(s) for the specimen(s); and (ii) Rendered the diagnosis(es).

Procedures/Addenda
Addendum

Status: Signed Out

Addendum Diagnosis

- E. **Station 5 lymph node #1:**
- Sections of bone and surrounding soft tissue show extensive fibrosis and adhesions. However, no malignancy is present.
- Therefore the tumor is considered: pT2, pN2, pMX

Addendum

Status: Signed Out

Addendum Diagnosis

Addendum (I):

- Bone fragments with trilineage hematopoietic elements.
- No carcinoma seen.

Intraoperative Consultation

- A. Left upper lobe biopsy, FS: Negative for malignancy.

[page 3 of 4]
- B. Left secondary carina, [REDACTED] Negative for malignancy.
- C. Station 4L mediastinal lymph node, [REDACTED] Negative for malignancy.
- D. Left lung tumor for frozen section for bronchial margins [REDACTED] Bronchial margin free of tumor.
- I. Left chest with ribs 2 R3 for representation margins short stitch superior, long stitch lateral [REDACTED] Chest wall margins (superior and superficial intercostal margins) free of tumor.
- [REDACTED]

Clinical History:

None Provided

Operation Performed

Bronchoscopy, mediastinoscopy, left upper lobectomy

Pre Operative Diagnosis:

Left lung cancer

Specimen(s) Received:

- A: Left upper lobe biopsy, [REDACTED]
B: Left secondary carina, [REDACTED]
C: Station 4L mediastinal lymph node, [REDACTED]
D: Left lung tumor for frozen section for bronchial margins [REDACTED]
E: Station 5 lymph node # 1
F: Station 5 lymph node # 2
G: Station 5 lymph node # 3
H: Station 9 lymph node
I: Left chest with ribs 2 R3 for representation margins short stitch superior, long stitch lateral, [REDACTED]

Gross Description:

- A. Received fresh is a pale tan tissue fragment, 0.2 x 0.1 x 0.1 cm and dark tissue fragment, 0.1 x 0.1 x 0.1 cm. In toto in one cassette for frozen section.
- B. Received fresh is a pale tan tissue fragment, 0.2 x 0.1 x 0.1 cm. In toto in one cassette for frozen section.
- C. Received fresh is a dark tissue fragment, 1.5 x 1.0 x 0.2 cm. Submitted in toto in one cassette for frozen section.
- D. Received in formalin is a left lung, weighing 718 grams, measuring 21.0 x 15.0 x 6.0 cm. There is a segment of bronchus 1.0 cm in length, 2.0 cm in diameter. The pleural surface is red-purple, smooth. At the upper pole, the pleural surface shows multiple elevated lesions, ranging from 0.1 to 1.0 cm in greatest dimension. One centimeter from bronchial resection margin, there is tumor mass 6.0 x 5.0 x 4.5 cm with hemorrhagic and necrotic areas. The pleural surface is inked in black. At the upper pole, there is a firm, consolidated area approximately 4.0 x 4.0 x 4.0 cm. Also at the hilum, there is an ovoid possible lymph node, 2.0 cm in greatest dimensions. Representative sections are submitted in ten cassettes as follows:
- 1 Bronchial margin for frozen section
- 2 Bronchus, 1.0 and 0.2 cm from resection margin
- 3-7 Tumor and lung parenchyma
- 8 Area at the apex of the lobe (consolidated area)
- 9&10 Lymph node bisected (submitted in toto), half in each cassette
- E. Received in formalin is an ovoid, yellow, pale tan tissue fragment, 1.0 x 1.0 x 0.2 cm. Bisected and submitted in toto in one cassette.
- F. Received in formalin is an ovoid pale tan tissue fragment, 2.0 x 1.0 x 1.0 cm. There are two possible lymph nodes, 1.0 cm each. One of them is bisected, the second one is trisected. Submitted in toto in two cassettes as follows:
- 1 One possible lymph node bisected
- 2 One possible lymph node trisected, submitted in toto

[page 4 of 4]
- G. Received in formalin are two ovoid pink-tan tissue fragments. The smaller one is 0.5 x 0.2 x 0.2 cm. The larger is 0.7 x 0.5 x 0.5 cm. The larger is inked in black. They are bisected and submitted in toto in one cassette.
- H. Received in formalin is an ovoid pale tan tissue fragment, 0.5 x 0.3 x 0.2 cm. The specimen is bisected and submitted in toto in one cassette.
- I. Received fresh is a segment of muscle tissue with attached ribs, 9.0 x 6.0 x 1.0 cm. The specimen is oriented with a short suture superior and long suture lateral. The inner aspect is inked in black. Representative sections are submitted in six cassettes as follows:
- 1-4 For frozen section
- 5&6 Bone tissue from the ribs for decalcification

Source: NCI Genomic Data Commons file 85f8e4a8-0cad-48b3-8870-92423c8297f7 (TCGA-52-7812.C7BB38E8-F472-437C-9D6E-7CFB6A5785B4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).